Gene-level copy-number profile of tumor specimen TCGA-AR-A1AJ-01A from TCGA case TCGA-AR-A1AJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AR-A1AJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.146bbf8b-4047-4e89-9463-abba54e8d992.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e569fb4-f924-4d35-9610-70245eaf80b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 22,554; copy number 2: 27,197; copy number 3: 5,392; copy number 4: 4,289; copy number 5: 80; copy number 7: 208; copy number 11: 79; copy number 12: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AJ-01A-21D-A12N-01): tumor purity 0.19, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 382 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,421,341–39,730,065, 69 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:41,490,396–43,030,535, 45 genes, copy number 7 (within-gene range 2–7): GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA.
- chr10:74,506,081–84,294,659, 163 genes, copy number 7 (broad region; genes not listed).
- chr12:4,368,227–4,694,317, 11 genes, copy number 5 (within-gene range 1–5): FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9.
- chr19:14,927,052–15,233,435, 15 genes, copy number 12: OR7A15P, OR7C2, SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3.
- chr19:28,883,430–28,970,874, 1 gene, copy number 11 (within-gene range 3–11): LINC00906.
- chr19:28,949,437–32,978,229, 78 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22,554. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
